TCGA case TCGA-AR-A2LM — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0bf6e772-1aa1-4f54-9a50-c1414e2f22f3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 49.4 years (18,053 days); Year of diagnosis: 2007; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 3; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Days to treatment start: 78 days; Days to treatment end: 141 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 78 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Days to treatment start: 120 days; Days to treatment end: 141 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Days to treatment start: 170 days; Days to treatment end: 967 days (2.6 years).
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,585 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,935 days (5.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,218.

Molecular and laboratory tests
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Test value range: 70-79%.
- PGR (IHC): Positive; Test value range: 70-79%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A2LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 490 mg.
  Slide TCGA-AR-A2LM-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 32; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-AR-A2LM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A2LM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 3: Pharmaceutical therapy drug name: Abraxane.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,935 days; disease-specific survival: no event (censored), 1,935 days; disease-free interval: no event (censored), 1,935 days; progression-free interval: no event (censored), 1,935 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A2LM-01A-11D-A17U-01): tumor purity 0.57, ploidy 2.06, whole-genome doublings 0.
